Surgical pathology report (de-identified scan), TCGA case TCGA-N5-A4RT, project TCGA-UCS (Uterine Carcinosarcoma), tissue source site MSKCC, specimen TCGA-N5-A4RT-01A (Primary Tumor).

[page 1 of 4]
ICD-O-3

Carcinoma / Mixed
Mullerian Tumor, malignant
8950/3

Site Endometrium C54.1

QW 4/2/13

Specimens Submitted:

- 1: SP: Uterus, cervix, bilateral tubes and ovaries
- 2: SP: Anterior abdominal wall nodule
- 3: SP: Bladder peritoneum
- 4: SP: Rectal adhesion
- 5: SP: Right uteral sacral biopsy
- 6: SP: Sentinel right external iliac lymph node
- 7: SP: Sentinel right obturator lymph node
- 8: SP: Right external iliac lymph node
- 9: SP: Right hypogastric lymph node
- 10: SP: Right obturator lymph node
- 11: SP: Right common iliac lymph node
- 12: SP: Sentinel left external iliac lymph node
- 13: SP: Sentinel left external iliac lymph node #2
- 14: SP: Left common iliac lymph node
- 15: SP: Left external iliac lymph node
- 16: SP: Left obturator lymph node
- 17: SP: Left internal iliac lymph node

DIAGNOSIS:

1. UTERUS, CERVIX, FALLOPIAN TUBES AND OVARIES; TOTAL HYSTERECTOMY AND BILATERAL SALPINGO-OOPHORECTOMY:
- MALIGNANT MIXED MULLERIAN TUMOR OF ENDOMETRIUM, WITHOUT HETEROLOGOUS ELEMENTS.
- THE TUMOR INVADES TO > HALF OF MYOMETRIUM.
- THE MAXIMAL THICKNESS OF MYOMETRIAL INVASION IS 11 MM.
- THE THICKNESS OF THE MYOMETRIUM IN THE AREA OF MAXIMAL TUMOR INVASION IS 16 MM.
- NO ENDOCERVICAL INVASION IS IDENTIFIED.
- VASCULAR INVASION IS PRESENT.
- THE MYOMETRIUM SHOWS THE FOLLOWING ABNORMALITY(IES): LEIOMYOMA(S).
- ALL ADNEXAE ARE UNREMARKABLE.
2. SOFT TISSUE, ANTERIOR ABDOMINAL WALL NODULE; BIOPSY:

** Continued on next page **

[page 2 of 4]
[REDACTED]

- BENIGN FIBROVASCULAR AND ADIPOSE TISSUE WITH A SIMPLE CYST.

3. PERITONEUM, BLADDER; BIOPSY:
- BENIGN FIBROVASCULAR AND ADIPOSE TISSUE WITH A SIMPLE CYST.
4. SOFT TISSUE, RECTAL ADHESION; BIOPSY:
- BENIGN FIBROVASCULAR AND ADIPOSE TISSUE.
5. SOFT TISSUE, RIGHT UTERAL SACRAL; BIOPSY:
- BENIGN FIBROVASCULAR AND ADIPOSE TISSUE WITH A SIMPLE CYST.
6. LYMPH NODE, SENTINEL, RIGHT EXTERNAL ILIAC; EXCISION:
- METASTATIC CARCINOMA IN 1 OF 2 LYMPH NODES (1/2).
7. LYMPH NODE, SENTINEL, RIGHT OBTURATOR; EXCISION:
- METASTATIC CARCINOMA IN 1 OF 1 LYMPH NODE (1/1).
8. LYMPH NODE, RIGHT EXTERNAL ILIAC; EXCISION:
- ONE BENIGN LYMPH NODE (0/1).
9. LYMPH NODE, RIGHT HYPOGASTRIC; EXCISION:
- BENIGN FIBROVASCULAR TISSUE. NO LYMPH NODE IDENTIFIED.
10. LYMPH NODES, RIGHT OBTURATOR; EXCISION:
- TWO BENIGN LYMPH NODES (0/2).
11. LYMPH NODES, RIGHT COMMON ILIAC; EXCISION:
- METASTATIC CARCINOMA IN 1 OF 2 LYMPH NODES (1/2).
12. LYMPH NODE, SENTINEL, LEFT EXTERNAL ILIAC; EXCISION:
- ONE BENIGN LYMPH NODE (0/1).
- DEEPER LEVEL RECUTS AND SPECIAL STAINS HAVE BEEN ORDERED. THE RESULTS WILL BE REPORTED IN AN ADDENDUM.
13. LYMPH NODE, SENTINEL, LEFT EXTERNAL ILIAC #2; EXCISION:
- ONE BENIGN LYMPH NODE (0/1).
- DEEPER LEVEL RECUTS AND SPECIAL STAINS HAVE BEEN ORDERED. THE RESULTS WILL BE REPORTED IN AN ADDENDUM.
14. LYMPH NODE, LEFT COMMON ILIAC; EXCISION:
- ONE BENIGN LYMPH NODE (0/1).
15. LYMPH NODE, LEFT EXTERNAL ILIAC; EXCISION:
- BENIGN FIBROVASCULAR AND ADIPOSE TISSUE. NO LYMPH NODE IDENTIFIED.
16. LYMPH NODE, LEFT OBTURATOR; EXCISION:
- ONE BENIGN LYMPH NODE (0/1).
17. LYMPH NODE, INTERNAL ILIAC; EXCISION:
- ONE BENIGN LYMPH NODE (0/1).

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF

** Continued on next page **

[page 3 of 4]
[REDACTED]

THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED
THIS REPORT.

[REDACTED]

*** Report Electronically Signed Out *** [REDACTED]

[REDACTED]

[page 4 of 4]
[REDACTED]

Procedures/Addenda:
Addendum

[REDACTED]

Addendum Diagnosis

ADDENDUM REPORT

[REDACTED]

SITE: SENTINEL LYMPH NODE(S), LEFT EXTERNAL ILIAC #1 AND #2 (PARTS 12 AND 13)

ADDITIONAL H&E STAINED SECTIONS AND IMMUNOHISTOCHEMICAL STAINS FOR CYTOKERATINS (AE1:AE3) SHOW NO EVIDENCE OF METASTATIC TUMOR.

[REDACTED]

** End of Report **

I/PAA Discrepancy		

Source: NCI Genomic Data Commons file 9ee5da6b-84e2-48eb-96de-ebbf66313d67 (TCGA-N5-A4RT.AD77201F-0CF7-4C9B-ABDE-94F4FCAF3C0C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).